Somatic mutation profile of tumor specimen TCGA-SN-A84X-01A (aliquot TCGA-SN-A84X-01A-11D-A435-10) from TCGA case TCGA-SN-A84X, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 21.4 years (7,833 days).
Specimen TCGA-SN-A84X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 614f5dc8-6f75-47c9-bb57-813aeb595f2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SN-A84X-10A (Blood Derived Normal), aliquot TCGA-SN-A84X-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef5b1e18-f9b3-48b9-ba27-f182fc0a0295

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Silent 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL6 | c.929C>T p.P310L (on ENST00000379240; = p.P335L on NM_001009185.3) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs772003187; called by muse, mutect2, varscan2
- CSRNP3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104405584, COSV58776305; called by muse, mutect2, varscan2
- FAM117B | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1228985904, COSV57417036; called by muse, mutect2, varscan2
- NR1I3 | c.778G>A p.E260K (on ENST00000367982 / NM_001077480.3; = p.E256K on NM_005122.5) | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.333); catalogued as rs1385727752; called by muse, mutect2, varscan2
- RBM17 | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1396291010, COSV65913921; called by muse, mutect2, varscan2
- SERINC5 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV72216497; called by muse, mutect2, varscan2
- ADAM9 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ARSG | c.401T>G p.I134R | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- C20orf27 | c.150C>G p.S50R (on ENST00000379772 / NM_001258429.2; = p.S75R on NM_001039140.3) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- C2orf16 | c.5230A>T p.S1744C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EDC4 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GPR68 | c.32_34del p.M11del | In Frame Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel, varscan2
- ILVBL | c.611T>G p.V204G | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- ITGAX | c.509T>A p.M170K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLC4 | c.1716G>T p.K572N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2
- PCDHB14 | c.1445C>A p.T482N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- PDS5A | c.2947A>G p.I983V | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.335); called by muse, mutect2
- USP15 | c.1243G>T p.D415Y (on ENST00000280377 / NM_001351159.2; = p.D386Y on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ARHGAP17 | c.840C>T p.G280= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV51507158; called by muse, mutect2, varscan2
- CCR9 | c.423C>T p.S141= (on ENST00000357632 / NM_031200.3; = p.S129= on NM_006641.4) | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs201764174; called by muse, mutect2, varscan2
- TMCC3 | c.348G>A p.E116= | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- ZBTB1 | c.1536G>A p.R512= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1210919324; called by muse, mutect2, varscan2
